Surgical pathology report (de-identified scan), TCGA case TCGA-39-5027, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site MSKCC, specimen TCGA-39-5027-01A (Primary Tumor).

[page 1 of 4]
Clinical Diagnosis & History:

with bloody cough, right lower lobe mass.

Specimens Submitted:

- 1: SP: Trucut needle bx left lower lobe lung mass
- 2: SP: Level seven mediastinal lymph nodes
- 3: SP: Right level nine mediastinal lymph nodes
- 4: SP: Right interlobar lymph nodes
- 5: SP: Level seven mediastinal lymph node
- 6: SP: Right lower lobe lung

DIAGNOSIS:

- 1) LUNG, LEFT LOWER LOBE; NEEDLE BIOPSY:
- INVASIVE SQUAMOUS CELL CARCINOMA.
- 2) LYMPH NODES, LEVEL VII MEDIASTINUM; EXCISION:
- LYMPH NODE FRAGMENTS NEGATIVE FOR METASTATIC CARCINOMA.
- 3) LYMPH NODES, RIGHT LEVEL IX MEDIASTINUM; EXCISION:
- ONE LYMPH NODE NEGATIVE FOR METASTATIC CARCINOMA (0/1).
- 4) LYMPH NODES, RIGHT INTERLOBAR; EXCISION:
- ONE LYMPH NODE NEGATIVE FOR METASTATIC CARCINOMA (0/1).
- 5) LYMPH NODE, LEVEL VII MEDIASTINUM; EXCISION:
- ONE LYMPH NODE NEGATIVE FOR METASTATIC CARCINOMA (0/1).
- 6) LUNG, RIGHT LOWER LOBE; LOBECTOMY:
- SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED, OF RIGHT LOWER LOBE.
- THE TUMOR MEASURES 5.0 CM IN GREATEST DIMENSION GROSSLY.
- NO VASCULAR INVASION IS IDENTIFIED.
- NO PERINEURAL INVASION IS IDENTIFIED.
- THE BRONCHIAL MARGIN IS FREE OF TUMOR.
- THE PLEURA IS FREE OF TUMOR.
- NO IN SITU CARCINOMA IS IDENTIFIED.
- THE NON-NEOPLASTIC LUNG SHOWS THE FOLLOWING ABNORMALITIES: EMPHYSEMATOUS CHANGES, RESPIRATORY BRONCHIOLITIS AND FOCAL PARENCHYMAL SCARRING.
- NO TUMOR IS SEEN IN TWO PERIBRONCHIAL LYMPH NODES (0/2).

** Continued on next page **

[page 2 of 4]
I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

1). The specimen is received fresh for frozen section consultation, labeled "Tru-cut needle biopsy, left lower lobe lung mass" and consists of three cores of pink tan soft tissue measuring 0.9 x 0.4 x 0.2cm in aggregate. Entirely submitted for frozen section.

Summary of sections:

-- frozen section control

2). The specimen is received fresh for frozen section consultation, labeled "Level 7 mediastinal lymph nodes" and consists of multiple tan black lymph nodes ranging from 0.3 cm up to 1.2 cm in greatest dimension. Entirely submitted for frozen section.

Summary of sections:

FSCA -- frozen section control A

FSCB. frozen section control B

3). The specimen is received in formalin, labeled "right level 9 mediastinal lymph nodes" and consists of single fragment of tan anthracotic tissue measuring 0.7 x 0.4 x 0.4 cm. The lymph node is entirely submitted.

Summary of sections:

LN- lymph node

4). The specimen is received in formalin, labeled "right interlobar lymph nodes" and consists of single fragment of anthracotic soft tissue measuring 0.9 x 0.6 x 0.5. The lymph node is entirely submitted.

Summary of sections:

LN- lymph node

** Continued on next page **

[page 3 of 4]
5). The specimen is received in formalin, labeled "level 7 mediastinal lymph node" and consists of single fragment of tan anthracotic tissue measuring 0.5 x 0.3 x 0.3 cm. The lymph node is entirely submitted.

Summary of sections:
LN- lymph node

6). The specimen is received fresh and is labeled, "right lower lobe lung". It consists of a 15.5 x 8.5 x 3.6 cm lung lobe with attached bronchus and blood vessels straddled by multiple staple lines, which weighs 292.0 gm (fixed weight). The attached bronchus measures 1.9 x 1.0 x 0.4 cm. The pleural surface is unremarkable. The pleural surface is inked black. Serial sectioning reveals an ill defined, subpleural 5 x 2.0 x 0.6 cm white, tan tumor mass on the medial surface, located 4.0 cm from the bronchial margin and 2.5 cm from the closest staple margin. The tumor is not associated with the bronchus. Paribronchial anthracotic lymph nodes are identified and submitted. The uninvolved lung parenchyma shows no significant abnormality. Representative sections are submitted. TPS is submitted. Photographs are taken.

Summary of sections:
BVM -- bronchovascular margin.
SM -- staple margin.
T-tumor
RA-uninvolved lung tissue away from tumor
RC-uninvolved lung tissue close to tumor
LN -- lymph nodes.

Summary of Sections:

Part 1: SP: Trucut needle bx left lower lobe lung mass

Block	Sect.	Site	PCs
1		FSC	1

Part 2: SP: Level seven mediastinal lymph nodes

Block	Sect.	Site	PCs
1		fsca	1
1		fsab	1

Part 3: SP: Right level nine mediastinal lymph nodes

Block	Sect.	Site	PCs
1		ln	1

Part 4: SP: Right interlobar lymph nodes

[page 4 of 4]
Block	Sect. Site	PCs
1	ln	1

Part 5: SP: Level seven mediastinal lymph node

Block	Sect. Site	PCs
1	ln	1

Part 6: SP: Right lower lobe lung

Block	Sect. Site	PCs
1	bvm	1
1	ln	1
4	ra	4
4	rc	4
2	sm	2
3	t	3

Intraoperative Consultation:

The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: INVASIVE SQUAMOUS CELL CARCINOMA.
PERMANENT DIAGNOSIS: SAME

2A,B) FROZEN SECTION DIAGNOSIS: NEGATIVE LYMPH NODES.
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file d576533d-d749-495b-a842-065b91a9b732 (TCGA-39-5027.02693E05-2498-437A-9C26-7DE09702C5EE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).